Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A2G0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A2G0-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3 (8380/3) (8441/3)
Carcinoma, mixed endometrioid + serous
case to highest 8441/3
Site: endometrium c54.1
lw 6/3/11

-- Surgical Pathology

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 J1 K1 L1 M1 N1 O1 P1
Q1 R1 S1
B1 T1 U1 C1 C2 C3 C4 C5 D1 D2 D3 D4 E1 F1 G1 H1 I1
Uterus, right ovary (2.1 x 1.8 x 1.2 cm) with 11.0 cm
segment of
right fallopian tube, and left ovary (2.0 x 1.6 x 1.0 cm)
with 9.0
cm segment of left fallopian tube together weighing 50.0
grams;
portion of omentum (30.0 x 18.0 x 3.0 cm); right and left
pelvic
lymph nodes; right and left para-aortic lymph nodes above
and below
the inferior mesenteric artery; right gonadal vessels
(11.0 cm in
length); left gonadal vessels (12.0 cm in length); and
staging
biopsies [large bowel serosa, large bowel mesentery, right
diaphragm, cul de sac, bladder peritoneum, left and right
colic
gutters, right and left pelvic sidewall, small bowel
serosa, and
small bowel mesentery ranging in size from 0.3 cm to 1.6
cm in
greatest dimension].

DIAGNOSIS:

Uterus, endometrium, hysterectomy: FIGO grade III (of
III) mixed
serous and endometrioid carcinoma is identified forming a
3.6 x 3.1
x 2.0 cm polypoid mass. The tumor invades 0.2 cm into the
myometrium (total myometrial thickness, 1.2 cm).
Angiolymphatic
invasion is absent. The lower uterine segment and cervix
are
uninvolved.

Uterus, myometrium, hysterectomy: No diagnostic
abnormalities.

Uterus, cervix, hysterectomy: No diagnostic
abnormalities.

[page 2 of 2]
Ovary and fallopian tube, right and left, salpingo-oophorectomy: No diagnostic abnormalities.

Omentum, omentectomy: Negative for tumor..

Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (4 external iliac, 7 internal iliac, 3 common iliac, 2 obturator) are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (3 external iliac, 4 internal iliac, 7 common iliac, 7 obturator) are negative for tumor.

Lymph nodes, left and right para-aortic above and below the inferior mesenteric artery, excision: Multiple para-aortic lymph nodes above the inferior mesenteric artery (3 left, 2 right) are negative for tumor. Multiple para-aortic lymph nodes below the inferior mesenteric artery (5 left, 3 right) are negative for tumor.

Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor.

Soft tissue; large bowel serosa, large bowel mesentery, right diaphragm, cul de sac, bladder peritoneum, left and right colic gutters, right and left pelvic sidewall, small bowel serosa, and small bowel mesentery; staging biopsies: Negative for malignancy, all sites.

Dual/Synchronous Pathology Noted		/

Source: NCI Genomic Data Commons file cbc7a0b6-5f4d-4d23-aee5-e21ad1ed1f94 (TCGA-D1-A2G0.02872006-6F7E-4FB7-B1C2-1C5DD3199FE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).